Surgical pathology report (de-identified scan), TCGA case TCGA-D5-7000, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-7000-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – cancer of the cecum.**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the cecum.**

Examination performed on:

Macroscopic description:

A 20 cm length of the large intestine with periintestinal fat tissue sized 18 x 5 x 3 and an 8 cm appendix. A cauliflower-shaped tumour sized 3 x 2 cm found in the mucosa. The lesion surrounds 80% of the intestine circumference, is located 3.5 cm from the proximal excision line and 1.5 cm from the distal excision line. Minimum side margin is 3 cm.

Microscopic description:**Adenocarcinoma tubulopapillare partim mucinosum (G3).****Lymphonodulitis (No XIV).****Appendix - Appendicitis chronica.**Preliminary result:**Adenocarcinoma tubulopapillare partim mucinosum coli. Tubulopapillar and partially mucinous adenocarcinoma of the colon.****(G3; DukesA; Astler-CollerBI; pT2; pNO).****Final diagnosis to be given after serial dilution of the specimens**

Compliance validated by:

Examination performed on:

Test result**Final result same as preliminary one.****Lymphonodulitis No XVIII.**

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 1904092c-d7a4-4b9b-9b4e-8053c060352a (TCGA-D5-7000.027E06D6-F4C5-433B-9B41-3A31678ED776.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).